Surgical pathology report (de-identified scan), TCGA case TCGA-MI-A75H, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MI-A75H-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver
c22.0
nos/13/13

--- SURGICAL PATHOLOGY ---

MEDICAL RECORD	SURGICAL PATHOLOGY
PATHOLOGY REPORT	
Laboratory:	Accession No.
Submitted by: SURGERY	Date obtained:
Specimen (Receiver):	
A. PARTIAL SEGMENT (6) LIVER RESECTION-FRESH	
BRIEF CLINICAL HISTORY:	
PREOPERATIVE DIAGNOSIS:	
Hepatocellular Carcinoma	
OPERATIVE FINDINGS:	
POSTOPERATIVE DIAGNOSIS:	
Hepatocellular Carcinoma	
Surgeon/physician:	
PATHOLOGY REPORT	
Laboratory:	Accession No.

GROSS DESCRIPTION:

The specimen consists of a 33.4 g, 8.0 x 3.9 x 2.9 cm, tan-brown, irregular soft tissue grossly consistent with segment of liver. The capsule is tan-pink to yellow and smooth to nodular. No gross evidence of mass is identified on the capsule. The resection margin is tan-brown and scabrous with abundant metallic clips. The resection margin is inked black, and the specimen is serially sectioned to reveal a 2.2 x 2.0 x 2.0 cm, tan-yellow to white, lobulated, well-demarcated mass that is 0.4 cm from the liver resection margin. The gross findings are communicated to the surgeon for an intraoperative gross consultation. The mass grossly abuts the overlying capsule.

The remaining liver parenchyma is tan-brown and unremarkable. No subsequent lesions are identified.

Representative sections are submitted as follows: A1-A9- entire mass with overlying capsule and liver resection margin; A10- uninvolved liver parenchyma away from mass. (Note: Representative portion is taken for tissue bank.)

MICROSCOPIC EXAM
DIAGNOSIS

LIVER, SEGMENT 6, PARTIAL RESECTION
- HEPATOCELLULAR CARCINOMA (SEE CANCER SUMMARY AND COMMENT)
- CIRRHOSIS

Surgical Pathology Cancer Case Summary
Based on AJCC/UICC TNM, 7th edition
- Specimen: liver
- Procedure: Partial hepatectomy, Minor hepatectomy
- Tumor Size: 2.2 x 2.0 x 2.0 cm
- Tumor Focality: Solitary
- Histologic Type: Hepatocellular carcinoma
- Histologic Grade:
- Tumor Extension: Tumor confined to liver
- Margins:

[page 2 of 2]
- Parenchymal Margin: 0.2 cm
- Lymph-Vascular Invasion:
- Macroscopic Venous (Large Vessel) Invasion: not identified
- Microscopic (Small Vessel) Invasion: Present
- Perineural Invasion: not identified
- Pathologic Staging (pTNM):
- No nodes submitted or found
- Additional Pathologic Findings:
- CIRRHOSIS (see comment)
- Clinical History (per CPRS chart):
- HEPATITIS C AND CROHN'S DISEASE
- ELEVATED LFTs AND AFP

Comment: In the fibrosis scoring methods the unaffected liver parenchyma scores Knodell 4/4, Metavir 4/4 and Ishak 6/6. concurs with the findings. notified on at

PATHOLOGIST
Signed

Source: NCI Genomic Data Commons file e82ed30b-6f29-445e-83d5-9b99d94ce9ee (TCGA-MI-A75H.57959509-A138-4131-BE87-9A77ED365702.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).